Somatic mutation profile of tumor specimen TCGA-12-3649-01A (aliquot TCGA-12-3649-01A-01W-0922-08) from TCGA case TCGA-12-3649, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.2 years (27,846 days).
Specimen TCGA-12-3649-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1ff27b0-dd0c-4895-a270-5a6ff8c97a15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-3649-10A (Blood Derived Normal), aliquot TCGA-12-3649-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/863745a2-1fe2-47b6-bba7-63eaf68b66ce

The open-access MAF lists 100 somatic variants for this specimen: 80 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 19, Nonsense Mutation 8, Frame Shift Ins 3, Frame Shift Del 3, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 182/413 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1027-2A>G p.X343_splice | Splice Site (SNP) | VAF 13/19 reads (68%) | hotspot (GDC flag); catalogued as rs1085308041, CS090868, CS110214, COSV64293079, COSV64296375; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTR5 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772935923, COSV54762280; called by muse, mutect2, varscan2
- ACTRT1 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs138725538, COSV64418994; called by muse, mutect2, varscan2
- ADAM7 | c.1947C>A p.C649* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV51536658; called by muse, mutect2
- ADGRA2 | c.2474dup p.I826Hfs*37 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs775086506; called by pindel, varscan2
- ANK2 | c.2968C>G p.R990G | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52154619, COSV52189578; called by muse, mutect2, varscan2
- BLM | c.2500A>T p.N834Y | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61927591; called by muse, mutect2, varscan2
- BMP5 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752442881, COSV63702034; called by muse, mutect2, varscan2
- CALM1 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.076); catalogued as COSV63663757; called by muse, mutect2, varscan2
- CCDC85A | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs554353955, COSV68151378; called by muse, mutect2, varscan2
- CCSER1 | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV61470195; called by muse, mutect2, varscan2
- CDH16 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55339892; called by muse, mutect2, varscan2
- CSMD1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs781692154, COSV68262082; called by muse, mutect2
- CUBN | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs745602995, COSV64727649; called by muse, mutect2, varscan2
- DIAPH2 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV61293091; called by muse, mutect2, varscan2
- DMD | c.10775G>C p.R3592T | Missense Mutation (SNP) | VAF 88/111 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58954914; called by muse, mutect2, varscan2
- EPHA10 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60405723; called by muse, mutect2, varscan2
- GC | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 141/279 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56739995; called by muse, mutect2, varscan2
- GPR161 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.084); catalogued as COSV54794867; called by muse, mutect2, varscan2
- GRIK2 | c.2192C>G p.S731C | Missense Mutation (SNP) | VAF 140/431 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV59773988; called by muse, mutect2, varscan2
- HJV | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as COSV100382372, COSV60951098; called by muse, mutect2
- HLA-DQA2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs144060347; called by muse, varscan2
- IGKJ1 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 83/205 reads (40%) | catalogued as rs768964011; called by muse, mutect2, varscan2
- KLF17 | c.82-1G>A p.X28_splice | Splice Site (SNP) | VAF 60/151 reads (40%) | catalogued as COSV64857046; called by muse, mutect2, varscan2
- KLHL1 | c.24C>A p.D8E | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV64768781, COSV64779717; called by muse, mutect2, varscan2
- LYST | c.10192C>T p.R3398* | Nonsense Mutation (SNP) | VAF 197/446 reads (44%) | catalogued as rs1451596846, COSV67703719; called by muse, mutect2, varscan2
- MAGEB16 | c.452T>A p.F151Y | Missense Mutation (SNP) | VAF 117/138 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV67874650; called by muse, mutect2, varscan2
- MAGEC2 | c.713T>A p.F238Y | Missense Mutation (SNP) | VAF 338/430 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56001580; called by muse, mutect2, varscan2
- MEP1B | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320548902, COSV52499975; called by muse, mutect2, varscan2
- MMS22L | c.3097C>T p.R1033* | Nonsense Mutation (SNP) | VAF 152/403 reads (38%) | catalogued as rs146474162, COSV51526670; called by muse, mutect2, varscan2
- MST1R | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs751907940, COSV56569560; called by muse, mutect2, varscan2
- MYH3 | c.5414C>T p.A1805V | Missense Mutation (SNP) | VAF 94/287 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs781063695, COSV56870191; called by muse, varscan2
- NLRP3 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs868611120; called by muse, mutect2
- OR52H1 | c.13A>C p.N5H (on ENST00000322653; = p.N11H on NM_001005289.1) | Missense Mutation (SNP) | VAF 216/496 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59506280; called by muse, mutect2, varscan2
- OR52I1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 44/590 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs766970198, COSV56170141; called by muse, mutect2
- OR52I2 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 119/602 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs138555035; called by muse, mutect2
- OR6K2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 129/326 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs778393764, COSV100656924, COSV62744127; called by muse, mutect2, varscan2
- OR8A1 | c.653C>A p.T218N | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as COSV52510538; called by muse, mutect2, varscan2
- PCDHGA1 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 143/337 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs766357788, COSV65295536; called by muse, mutect2, varscan2
- PCLO | c.13637C>T p.T4546M | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs576824740, COSV61620329; called by muse, mutect2, varscan2
- PCNT | c.8473G>A p.E2825K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV64032461; called by muse, mutect2, varscan2
- PLEKHA5 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752042146, COSV54711427; called by muse, mutect2, varscan2
- PMM1 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53449514; called by muse, mutect2
- PPP4R4 | c.590T>A p.L197* | Nonsense Mutation (SNP) | VAF 43/147 reads (29%) | catalogued as COSV58558431; called by muse, mutect2, varscan2
- RYR2 | c.4990G>A p.V1664I | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs749434532, COSV63698965, COSV63705585; called by muse, mutect2, varscan2
- RYR2 | c.14833C>G p.Q4945E | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV63661988, COSV63715070; called by muse, mutect2, varscan2
- SALL4 | c.3056C>G p.S1019C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53856306; called by muse, mutect2, varscan2
- SCN9A | c.1659T>A p.S553R | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV57625051; called by muse, mutect2, varscan2
- SERPINA11 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58242138, COSV58243338; called by muse, mutect2, varscan2
- SIPA1L1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV62173831; called by muse, mutect2, varscan2
- SLC16A6 | c.294dup p.L99Afs*34 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | catalogued as rs782184620; called by mutect2, varscan2
- SLC27A2 | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 103/322 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1252465975, COSV51063254; called by muse, mutect2, varscan2
- SLC2A1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1017082606, COSV65288531; called by muse, mutect2, varscan2
- SLC4A10 | c.2704A>T p.K902* (on ENST00000446997 / NM_001354461.2; = p.K872* on NM_022058.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV55800657; called by muse, mutect2, varscan2
- SPRY3 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 179/379 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57144517; called by muse, mutect2, varscan2
- SULT1C3 | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 135/442 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV61254715; called by muse, mutect2, varscan2
- TESK1 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs764988346, COSV52412241; called by muse, mutect2, varscan2
- TMEM26 | c.690C>A p.N230K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.107); catalogued as COSV53264426; called by muse, mutect2, varscan2
- TRIM6 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 98/293 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748199490, COSV53475055; called by muse, mutect2, varscan2
- TRIM6 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs973284825, COSV53479248; called by muse, mutect2, varscan2
- TSSK1B | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs371461523; called by muse, mutect2, varscan2
- TTN | c.54896A>T p.H18299L (on ENST00000591111; = p.H10875L on NM_003319.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | PolyPhen benign (0.436); catalogued as COSV60360252; called by muse, mutect2, varscan2
- TTN | c.23503G>C p.V7835L (on ENST00000591111; = p.V6908L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/147 reads (24%) | PolyPhen benign (0.141); catalogued as COSV60334381; called by muse, mutect2, varscan2
- TUBA3C | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.117); catalogued as rs756491837, COSV67139538; called by muse, mutect2, varscan2
- VRTN | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56443846; called by muse, mutect2, varscan2
- ZFC3H1 | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV66436024; called by muse, mutect2, varscan2
- ZSCAN5B | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 26/149 reads (17%) | catalogued as rs555339343, COSV62841011; called by muse, mutect2, varscan2
- BAX | c.223del p.E75Sfs*5 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by pindel, varscan2
- BRPF3 | c.1612del p.Q538Rfs*8 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- C12orf50 | c.536_537del p.I179Kfs*11 | Frame Shift Del (DEL) | VAF 91/227 reads (40%) | called by mutect2, pindel, varscan2
- CDK11B | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- CHSY3 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- DSEL | c.3397C>T p.Q1133* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- MACF1 | c.7159T>C p.C2387R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- P4HA2 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- SLC2A11 | c.1273G>T p.G425* (on ENST00000345044 / NM_001024938.4; = p.G432* on NM_030807.5) | Nonsense Mutation (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- TBC1D19 | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- ZSWIM8 | c.1135T>G p.Y379D | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD13B | c.1170T>A p.I390= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV61472108; called by muse, mutect2, varscan2
- CBLN2 | c.153G>A p.A51= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV54052027; called by muse, mutect2
- CEACAM18 | c.792G>A p.K264= | Silent (SNP) | VAF 97/354 reads (27%) | catalogued as COSV67284251; called by muse, mutect2, varscan2
- CHRNA10 | c.1047C>T p.C349= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs555234421, COSV51707349; called by muse, mutect2
- CPAMD8 | c.1905A>G p.S635= (on ENST00000651564; = p.S588= on NM_015692.5) | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV52240024; called by muse, mutect2, varscan2
- CR2 | c.1251C>A p.L417= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV65509703; called by muse, mutect2, varscan2
- FITM2 | c.114C>T p.L38= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- GCN1 | c.2259T>A p.P753= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV56115100; called by muse, mutect2, varscan2
- HECTD4 | c.1938C>T p.P646= | Silent (SNP) | VAF 37/322 reads (11%) | called by muse, mutect2, varscan2
- ITIH1 | c.804C>T p.C268= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs752722689, COSV56258649; called by muse, mutect2, varscan2
- KCNQ2 | c.1494C>T p.I498= (on ENST00000359125 / NM_172107.4; = p.I470= on NM_004518.6) | Silent (SNP) | VAF 44/68 reads (65%) | called by muse, mutect2
- MTNR1B | c.312C>T p.D104= | Silent (SNP) | VAF 167/474 reads (35%) | catalogued as rs139515067; called by muse, mutect2, varscan2
- MUC3A | c.7485G>A p.S2495= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as rs79067082, COSV60210457; called by muse, mutect2, varscan2
- MYO10 | c.972G>A p.R324= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV72563640; called by muse, mutect2
- NBPF10 | c.11073A>T p.G3691= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs781839675, COSV61673670; called by muse, mutect2
- PMS2 | c.387G>T p.A129= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- SYNE2 | c.16416G>A p.L5472= | Silent (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- TGIF2LX | c.492G>A p.K164= | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as COSV52213391, COSV52215223; called by muse, mutect2, varscan2
- ZNF493 | c.612T>C p.I204= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV62752440; called by muse, mutect2, varscan2
- MIR515-1 | n.12C>T | RNA (SNP) | VAF 671/974 reads (69%) | called by muse, mutect2, varscan2
